Somatic mutation profile of tumor specimen MP2PRT-PASRPG-TMP1-A (aliquot MP2PRT-PASRPG-TMP1-A-1-0-D-A80J-36) from MP2PRT case MP2PRT-PASRPG, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 7.8 years (2,851 days).
Specimen MP2PRT-PASRPG-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9f9e158e-e57b-4f2f-b3a0-2608c423f7db.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PASRPG-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PASRPG-NB1-A-1-0-D-A80J-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/eb0a04eb-7449-49de-87a5-0d6d041b54c0

The open-access MAF lists 9 somatic variants for this specimen: 8 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 7, Frame Shift Ins 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CPXCR1 | c.619C>T p.P207S | Missense Mutation (SNP) | VAF 211/455 reads (46%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.563); catalogued as rs1197944995; called by muse, mutect2, varscan2
- PORCN | c.427C>T p.R143W | Missense Mutation (SNP) | VAF 231/558 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs781876014, COSV58225885; called by muse, mutect2, varscan2
- PRKAB1 | c.260G>C p.G87A | Missense Mutation (SNP) | VAF 146/340 reads (43%) | SIFT tolerated (0.18); PolyPhen benign (0.033); catalogued as COSV57554668, COSV57554715; called by muse, varscan2
- ELAPOR1 | c.182G>A p.C61Y | Missense Mutation (SNP) | VAF 114/293 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FREM1 | c.658G>T p.G220C | Missense Mutation (SNP) | VAF 134/152 reads (88%) | SIFT deleterious (0); PolyPhen possibly damaging (0.502); called by muse, mutect2, varscan2
- MTF1 | c.1800dup p.T601Yfs*9 | Frame Shift Ins (INS) | VAF 114/346 reads (33%) | called by mutect2, pindel, varscan2
- PRKCE | c.479T>C p.V160A | Missense Mutation (SNP) | VAF 204/508 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- USP53 | c.882G>T p.M294I | Missense Mutation (SNP) | VAF 135/363 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- KLHL38 | c.714C>T p.N238= | Silent (SNP) | VAF 173/413 reads (42%) | catalogued as rs771062095, COSV58087252; called by muse, mutect2, varscan2
